Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GO, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GO-01A (Primary Tumor).

Pathology Report

DOB:
Physician:

Sex: F

Collected:

Received: 1

Case type: Surgical Case

Accession:

DIAGNOSIS

(A) RIGHT LOBE THYROID AND ISTHMUS:

PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Right lobe

Multi-focal: No

Size = 3.2 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Lymph nodes: No tumor present in 4 lymph nodes

1CD-0-3

Path: carcinoma, papillary, follicular variant 8340/3

Site: thyroid, NOS C73.9

11/30/11

CQCF: carcinoma, papillary, thyroid 8260/3

for TCGA- follicular variant 8260/3

GROSS DESCRIPTION

(A) RIGHT LOBE THYROID AND ISTHMUS - A right lobe of thyroid (4.0 x 3.2 x 1.5 cm) with isthmus (1.2 x 0.3 x 0.2 cm). Sectioning of the right lobe has a well circumscribed pink, soft nodule measuring 3.2 x 2.4 x 2.1 cm. No capsule is grossly identified. The adjoining thyroid tissue is grossly unremarkable. The remaining entire tissue is submitted.

SECTION CODE: A1, representative section from the nodule submitted for frozen section diagnosis; A2, superior pole of the right lobe and isthmus; A3-A12, entire nodule superior to inferior.

*FS/DX: INDETERMINATE FOLLICULAR NODULE, DEFER TO PERMANENT SECTIONS AND COMPLETE PROCESSING OF NODULE.

CLINICAL HISTORY

Right thyroid nodule.

CONSULTANT(S)

SNOMED CODES

T-B6000, M-83403

*Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration.

These tests have not been specifically cleared or

Source: NCI Genomic Data Commons file 05e0b3f5-25a6-4eb8-962f-bf186a50b39d (TCGA-EL-A3GO.8DAD2F04-A959-479D-B58F-39D081026080.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).